Gene-level copy-number profile of tumor specimen REBC-ADL9-TTM1-A from REBC case REBC-ADL9, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADL9-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2882c4c-61f2-4319-a362-93c885ed29cd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADL9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/90288322-5495-4f58-ac4a-7f068aa2237a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 25; copy number 2: 58,379.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
